Somatic mutation profile of tumor specimen TCGA-X6-A7WA-01A (aliquot TCGA-X6-A7WA-01A-12D-A351-09) from TCGA case TCGA-X6-A7WA, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-X6-A7WA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a8206d5-ec29-4c70-96c4-a44433a40d1e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X6-A7WA-10A (Blood Derived Normal), aliquot TCGA-X6-A7WA-10A-01D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7ef4397-c6fa-417d-ae5d-6e60d3de8ccb

The open-access MAF lists 115 somatic variants for this specimen: 95 protein-altering or splice-affecting, 15 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 15, Nonsense Mutation 7, Intron 4, Splice Site 2, 3'UTR 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1C | c.1217+405G>A | Intron (SNP) | VAF 17/44 reads (39%) | catalogued as rs79891110, CM045452, COSV100215020, COSV100223378; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 28/30 reads (93%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCY8 | c.1076C>A p.A359D | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV99654902; called by muse, mutect2
- ADGRE3 | c.766G>C p.E256Q | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.109); catalogued as COSV99506852; called by muse, mutect2, varscan2
- ADGRG2 | c.1370C>A p.A457D (on ENST00000379869 / NM_001079858.3; = p.A454D on NM_005756.4) | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as COSV100492833; called by muse, mutect2
- AL136295.1 | c.2315C>A p.A772E | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.239); catalogued as rs1299337827, COSV99938369; called by muse, mutect2
- ANK3 | c.1172C>A p.A391D | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV99782937; called by mutect2, varscan2
- ANKRD17 | c.1763C>A p.A588D | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100430126; called by muse, mutect2
- ARSD | c.1711C>A p.P571T | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV101144861; called by muse, mutect2
- ATP2B2 | c.923C>A p.A308E (on ENST00000352432; = p.A319E on NM_001001331.4) | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.433); catalogued as COSV100660604; called by muse, mutect2
- B4GALNT2 | c.1444C>T p.R482* | Nonsense Mutation (SNP) | VAF 19/35 reads (54%) | catalogued as rs201141534, COSV55924371; called by muse, mutect2, varscan2
- BRDT | c.907G>T p.A303S | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.059); catalogued as COSV100746627; called by muse, mutect2
- CALML4 | c.319C>A p.L107M | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100682893; called by muse, mutect2
- CCNE2 | c.74C>A p.A25D | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV100353907; called by mutect2, varscan2
- CCT4 | c.599C>A p.A200D | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.02); catalogued as COSV101075446; called by muse, mutect2
- CDS1 | c.966G>T p.E322D | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as COSV99881202; called by muse, mutect2
- CEP250 | c.4734G>T p.E1578D | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.129); catalogued as rs781717794, COSV100699247; called by mutect2, varscan2
- CFAP251 | c.1984G>T p.A662S | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1273744161, COSV56615580, COSV99996577; called by muse, mutect2
- CNOT10 | c.423G>T p.E141D | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV100095251; called by muse, mutect2
- CNTN3 | c.668G>C p.G223A | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV99726383; called by muse, mutect2, varscan2
- CUL4B | c.671T>A p.V224E | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100341311; called by muse, mutect2, varscan2
- CXCL5 | c.108C>G p.S36R | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.098); catalogued as COSV99932965; called by muse, mutect2, varscan2
- DHX36 | c.2665C>T p.H889Y | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.401); catalogued as COSV100274034; called by muse, mutect2, varscan2
- DNAJC21 | c.1044G>T p.Q348H | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.554); catalogued as COSV100331627; called by muse, mutect2
- EFCAB13 | c.2821C>A p.Q941K | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as COSV100517026; called by muse, mutect2, varscan2
- EFCAB6 | c.3308A>G p.Y1103C | Missense Mutation (SNP) | VAF 58/100 reads (58%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.502); catalogued as COSV99414662; called by muse, mutect2, varscan2
- EPC2 | c.475G>C p.E159Q | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV99310333; called by muse, mutect2, varscan2
- FAM135B | c.915G>C p.K305N | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.879); catalogued as COSV99428538; called by muse, mutect2, varscan2
- FANCI | c.2453T>G p.F818C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1427712731, COSV100168703; called by muse, mutect2, varscan2
- FASTKD5 | c.841C>A p.L281I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.952); catalogued as COSV99418698; called by muse, mutect2, varscan2
- FERMT1 | c.1729A>G p.S577G | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as CD119405, COSV99452257; called by muse, mutect2, varscan2
- GATAD2A | c.1607C>T p.T536M | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs751116404, COSV53077175; called by muse, mutect2, varscan2
- HM13 | c.841A>G p.I281V | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as rs754913862, COSV100159858; called by muse, mutect2, varscan2
- ILF3 | c.1549-1G>T p.X517_splice | Splice Site (SNP) | VAF 8/65 reads (12%) | catalogued as COSV99140443; called by muse, mutect2
- IQCH | c.2544G>T p.Q848H | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.213); catalogued as COSV100246437; called by muse, mutect2
- ITGB8 | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99752630; called by muse, mutect2
- L3MBTL3 | c.80C>T p.T27M | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs772613559, COSV100696466; called by muse, mutect2, varscan2
- LIMCH1 | c.2319G>T p.E773D | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV58301187; called by muse, mutect2
- MEGF10 | c.2476G>T p.A826S | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.217); catalogued as COSV99175873; called by muse, mutect2
- MMP21 | c.1074C>G p.F358L | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs749348073, COSV100916704, COSV64290452; called by muse, mutect2, varscan2
- MMP21 | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 21/54 reads (39%) | catalogued as rs751663187, COSV100916705; called by muse, mutect2, varscan2
- MMP21 | c.160C>G p.Q54E | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.063); catalogued as COSV100916706; called by muse, varscan2
- MMP21 | c.85C>T p.H29Y | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as COSV100916707; called by muse, varscan2
- MUC16 | c.34814C>A p.S11605* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | catalogued as COSV101202149; called by muse, mutect2
- MYO7B | c.6240G>C p.E2080D | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100265107; called by muse, varscan2
- NAALADL1 | c.233A>G p.D78G | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.028); catalogued as COSV100368307; called by muse, mutect2, varscan2
- NISCH | c.3082G>T p.A1028S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV100617730; called by muse, mutect2
- NLRC3 | c.2054C>A p.A685D | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV57087026; called by mutect2, varscan2
- NMI | c.8C>A p.A3D | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); catalogued as COSV99693556; called by muse, mutect2
- NOP9 | c.326T>C p.M109T | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.025); catalogued as COSV99351244; called by muse, mutect2, varscan2
- NRDC | c.2570C>A p.A857D | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV100703990; called by muse, mutect2
- OASL | c.960C>G p.D320E | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); catalogued as COSV99984685; called by muse, mutect2, varscan2
- OR5M8 | c.130A>G p.M44V | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs761531436, COSV100510811; called by muse, mutect2, varscan2
- PAK6 | c.1645G>T p.A549S | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99545184; called by muse, mutect2
- PKP4 | c.2953G>T p.A985S | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (1); PolyPhen possibly damaging (0.589); catalogued as COSV100734024; called by muse, mutect2
- POLR3B | c.2714-1G>C p.X905_splice | Splice Site (SNP) | VAF 6/48 reads (13%) | catalogued as COSV99943967; called by muse, mutect2
- PPM1D | c.628G>T p.A210S | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV100011251; called by muse, mutect2
- PTK2 | c.735G>C p.E245D | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV100571344; called by muse, mutect2, varscan2
- RAB27B | c.213G>T p.Q71H | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100024403, COSV50494280; called by muse, mutect2
- RABGAP1L | c.1879G>T p.A627S | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99275095; called by muse, mutect2
- RBM15 | c.1250G>T p.G417V | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100873528; called by muse, mutect2, varscan2
- RELN | c.3871C>T p.R1291* | Nonsense Mutation (SNP) | VAF 25/60 reads (42%) | catalogued as COSV100635133, COSV59021318; called by muse, mutect2, varscan2
- RNF43 | c.1347C>A p.S449R | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101348580, COSV68457894; called by muse, mutect2
- SAMSN1 | c.1000T>A p.C334S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as COSV99582659; called by muse, mutect2, varscan2
- SCYL3 | c.719T>C p.L240P | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100884333; called by muse, mutect2, varscan2
- SEMA5A | c.640C>A p.L214I | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs1283377897; called by muse, mutect2
- SLC2A9 | c.1559C>A p.A520E | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV99305798; called by muse, mutect2
- SMAP2 | c.837G>T p.M279I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV101019392; called by muse, mutect2, varscan2
- SON | c.4790G>T p.G1597V | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as COSV99280260; called by muse, mutect2
- SORL1 | c.5270G>T p.S1757I | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV99495805; called by muse, mutect2
- SUSD3 | c.447G>T p.Q149H | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100968928; called by muse, mutect2
- TDRD5 | c.2631G>T p.Q877H | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV99677479; called by muse, mutect2
- TENM1 | c.4733C>A p.A1578E | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.061); catalogued as COSV64427190; called by muse, mutect2
- TGFB1I1 | c.883C>T p.R295* (on ENST00000394863 / NM_001042454.3; = p.R278* on NM_015927.4) | Nonsense Mutation (SNP) | VAF 12/57 reads (21%) | catalogued as COSV62358965; called by muse, mutect2, varscan2
- THADA | c.2155C>T p.Q719* | Nonsense Mutation (SNP) | VAF 18/113 reads (16%) | catalogued as COSV100369675; called by muse, mutect2, varscan2
- TMTC2 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as COSV100339014; called by muse, mutect2
- TTC3 | c.2666T>G p.F889C | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100696160; called by muse, mutect2, varscan2
- TXLNB | c.811C>A p.L271I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100625220; called by mutect2, varscan2
- UNC13A | c.2233G>T p.E745* | Nonsense Mutation (SNP) | VAF 23/41 reads (56%) | catalogued as COSV99409875; called by muse, mutect2, varscan2
- VASN | c.212G>T p.S71I | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); catalogued as COSV99228255; called by muse, mutect2
- ZDHHC11 | c.44C>A p.A15D | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV99363769; called by mutect2, varscan2
- ZNF281 | c.461C>A p.A154D | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as COSV99664588; called by muse, mutect2, varscan2
- ZNF528 | c.1688G>T p.G563V | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.182); catalogued as COSV100846785; called by muse, mutect2
- ZNF831 | c.2308G>A p.G770R | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as COSV100926324; called by muse, mutect2, varscan2
- BIN1 | c.1030C>A p.P344T | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- GPR139 | c.898C>A p.L300I | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.232); called by muse, mutect2
- IGHV3-72 | c.26T>C p.F9S | Missense Mutation (SNP) | VAF 69/168 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- KIF27 | c.3354_3356del p.N1118del | In Frame Del (DEL) | VAF 32/83 reads (39%) | called by mutect2, pindel, varscan2
- KPNB1 | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- MAMSTR | c.1190C>A p.A397D (on ENST00000318083 / NM_001130915.2; = p.A294D on NM_182574.2) | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- MTSS1 | c.929C>A p.A310D | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- NUP205 | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PTCH1 | c.338C>A p.A113E | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- RB1 | c.356_380del p.E119Vfs*9 | Frame Shift Del (DEL) | VAF 28/57 reads (49%) | called by mutect2, pindel, varscan2
- SRCAP | c.2118G>T p.K706N | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- THOC2 | c.3794C>A p.A1265D | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.143); called by mutect2, varscan2
- CASR | c.1020G>A p.R340= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs773927063, COSV56135936, COSV56136915; called by muse, mutect2, varscan2
- JOSD2 | c.198C>A p.G66= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as COSV100976076; called by muse, mutect2
- KIF13A | c.2865C>A p.G955= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV99438813; called by muse, mutect2
- OTOGL | c.3933C>T p.H1311= (on ENST00000547103; = p.H1302= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs1485913470, COSV101509535; called by muse, mutect2, varscan2
- PALB2 | c.336C>T p.G112= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs1293127133, COSV99847910, COSV99848379; ClinVar: likely benign; called by muse, mutect2, varscan2
- PATZ1 | c.732C>T p.P244= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV99315690; called by muse, mutect2, varscan2
- PCBP4 | c.879C>A p.G293= (on ENST00000322099 / NM_033010.2; = p.G250= on NM_020418.4) | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100437202; called by muse, mutect2, varscan2
- RAMP1 | c.279C>T p.F93= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV99615023; called by mutect2, varscan2
- SCYL3 | c.718C>T p.L240= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as COSV100884334; called by muse, mutect2, varscan2
- SIPA1 | c.555G>T p.V185= | Silent (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- SNX13 | c.280T>C p.L94= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as COSV101285207; called by muse, mutect2, varscan2
- TECPR2 | c.3774T>A p.I1258= | Silent (SNP) | VAF 27/55 reads (49%) | catalogued as COSV63973323; called by muse, mutect2, varscan2
- TEP1 | c.7668C>A p.G2556= | Silent (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- TRIM54 | c.9C>T p.F3= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV99940676; called by muse, mutect2, varscan2
- VPS18 | c.384A>T p.G128= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV99592847; called by muse, mutect2, varscan2
- CIRBP | c.-7+416G>T | Intron (SNP) | VAF 4/44 reads (9%) | catalogued as COSV100309921; called by muse, mutect2
- NT5C1B-RDH14 | c.*212C>A | 3'UTR (SNP) | VAF 6/72 reads (8%) | catalogued as COSV67119099; called by muse, mutect2
- RGS3 | c.3081-208G>T | Intron (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- ZNF783 | c.802+3186G>T | Intron (SNP) | VAF 5/36 reads (14%) | catalogued as COSV100954308; called by muse, mutect2
